Somatic mutation profile of tumor specimen TCGA-J4-A83J-01A (aliquot TCGA-J4-A83J-01A-11D-A364-08) from TCGA case TCGA-J4-A83J, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.3 years (24,960 days).
Specimen TCGA-J4-A83J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6646a607-ff45-4bef-97d1-85007a7250e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A83J-10B (Blood Derived Normal), aliquot TCGA-J4-A83J-10B-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/080c68c7-789b-492a-aae4-9c7ce1c079c0

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 30, Silent 19, In Frame Del 3, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.398T>G p.F133C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1057519967, COSV61653174, COSV61653874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs1560311554, COSV53199004; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASNSD1 | c.1054_1056del p.L352del | In Frame Del (DEL) | VAF 23/118 reads (19%) | catalogued as rs758018468; called by pindel, varscan2
- CAB39 | c.482T>C p.L161S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99300053; called by muse, mutect2, varscan2
- CDCA2 | c.2062A>C p.N688H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV100399073; called by muse, mutect2, varscan2
- CEMIP | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs746486710, COSV99586535, COSV99586848; called by muse, mutect2, varscan2
- CFAP46 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs141623050; called by muse, mutect2, varscan2
- CHD4 | c.2579A>G p.D860G (on ENST00000357008 / NM_001363606.2; = p.D873G on NM_001273.5) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58902257; called by muse, mutect2, varscan2
- CHM | c.898A>G p.T300A | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100753574; called by muse, mutect2, varscan2
- DAAM2 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs564327973, COSV99226717; called by muse, mutect2, varscan2
- DOCK1 | c.4745A>G p.H1582R | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99732021; called by muse, mutect2, varscan2
- EPB41L2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774621932, COSV100441264; called by muse, mutect2
- FIG4 | c.1253T>G p.M418R | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100020135; called by muse, mutect2
- G6PC3 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV99291338; called by muse, mutect2, varscan2
- HDHD5 | c.727G>A p.A243T (on ENST00000336737 / NM_033070.3; = p.A213T on NM_017829.5) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99324981; called by muse, mutect2
- IRAK3 | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99706374; called by muse, varscan2
- KANSL3 | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs532815065, COSV100831231; called by muse, mutect2, varscan2
- KIF1A | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs868067075, COSV100242073; called by muse, mutect2, varscan2
- KMT2E | c.3772G>T p.V1258L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99996829; called by muse, mutect2, varscan2
- LRRC27 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100689902; called by muse, mutect2
- MAP3K8 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV99552291; called by muse, mutect2, varscan2
- MFHAS1 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1404230952, COSV99359851; called by muse, mutect2, varscan2
- NCKAP5 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100493901; called by muse, mutect2, varscan2
- NDST3 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs150758016; called by muse, mutect2, varscan2
- NDUFAF6 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV99712865; called by muse, mutect2, varscan2
- OR10Q1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.602); catalogued as rs757666569, COSV57470893; called by mutect2, varscan2
- PITRM1 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs975433124, COSV99829465; called by muse, mutect2, varscan2
- RBM6 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369268393; called by muse, mutect2, varscan2
- SLX4 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99568420; called by muse, mutect2, varscan2
- TEX15 | c.7753G>A p.D2585N (on ENST00000256246; = p.D2968N on NM_001350162.2) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1305546189, COSV99821944, COSV99822213; called by muse, mutect2, varscan2
- UGT2B7 | c.550A>G p.S184G | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100535297; called by muse, mutect2, varscan2
- ZNF236 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 7/186 reads (4%) | catalogued as COSV99471035; called by muse, mutect2
- DNAH3 | c.3121del p.M1041Cfs*7 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- ERN1 | c.2009del p.Q670Rfs*20 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- FAM47B | c.1702_1704del p.I568del | In Frame Del (DEL) | VAF 40/72 reads (56%) | called by mutect2, pindel, varscan2
- PEAK1 | c.351_353del p.N120del | In Frame Del (DEL) | VAF 30/147 reads (20%) | called by mutect2, pindel, varscan2
- RPS9 | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- RRN3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 3/88 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); called by muse, mutect2
- ABCA1 | c.402G>A p.Q134= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV101035733; called by muse, mutect2
- CAMK4 | c.987G>A p.A329= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs752495726, COSV100000084; called by muse, mutect2, varscan2
- COG7 | c.942G>T p.L314= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100207753; called by muse, mutect2, varscan2
- DPYSL5 | c.357G>A p.L119= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99982702; called by muse, mutect2, varscan2
- F13B | c.618A>T p.P206= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100803396; called by muse, mutect2, varscan2
- FOXP1 | c.1188G>A p.S396= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs138465768; called by muse, mutect2, varscan2
- GPR158 | c.2643C>T p.S881= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs753266335, COSV66266876; called by muse, mutect2, varscan2
- GRIK3 | c.2748T>A p.P916= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100902246; called by muse, mutect2
- MED24 | c.1908T>A p.R636= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV62418712; called by muse, mutect2
- MET | c.2319G>A p.P773= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs141733128, COSV100577325; ClinVar: likely benign; called by muse, mutect2, varscan2
- NRG1 | c.162C>T p.V54= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as rs949953365, COSV55155101; ClinVar: likely benign; called by muse, mutect2
- OR5L1 | c.63T>A p.P21= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as COSV100450198; called by muse, mutect2, varscan2
- RNF213 | c.13392C>T p.P4464= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs768624860; called by muse, mutect2
- RPS9 | c.399C>T p.R133= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100256464; called by muse, mutect2
- TMEM143 | c.819G>A p.T273= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99507231; called by muse, mutect2, varscan2
- TMEM192 | c.387C>A p.I129= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100122186; called by muse, mutect2, varscan2
- UGT2B7 | c.213T>C p.A71= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100535295; called by muse, mutect2, varscan2
- UTRN | c.3054C>T p.L1018= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs960422041, COSV62341901; called by muse, mutect2
- ZNF688 | c.795C>T p.F265= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV56301058; called by muse, mutect2, varscan2
